Somatic mutation profile of tumor specimen 0DPZTY from CCDI case PBCEJN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 7.7 years (2,815 days).
Specimen 0DPZTY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fba65140-bd72-49c2-b3ce-71639780500e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPZUF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c8edf87-ac2b-4e52-843b-afd189fa46a6

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEL | c.1796C>T p.T599M (on ENST00000673714; = p.T596M on NM_001807.6) | Missense Mutation (SNP) | VAF 52/541 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.855); catalogued as rs1267029539; called by muse, varscan2
- DTWD1 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 95/708 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as COSV99233704; called by muse, varscan2
- FAM9A | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 107/609 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as rs763112096, COSV66813237; called by muse, varscan2
- NIBAN1 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 146/833 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.146); catalogued as rs757707889, COSV62287717; called by muse, varscan2
- PADI3 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs35624745; called by muse, varscan2
- PRKD2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs763539356, COSV99354200; called by muse, varscan2
- ZNF213 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 76/405 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780855159, COSV67727489; called by muse, varscan2
- ADCY4 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 85/395 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.292); called by muse, varscan2
- CTBP1 | c.1229del p.G410Afs*103 | Frame Shift Del (DEL) | VAF 44/320 reads (14%) | called by pindel, varscan2
- DNAH2 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 68/554 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.413); called by muse, varscan2
- POLK | c.1271A>T p.E424V | Missense Mutation (SNP) | VAF 318/1054 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- PSKH1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, varscan2
- TEX37 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 118/682 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.872); called by muse, varscan2
- ZNF517 | c.34-4G>T | Splice Region (SNP) | VAF 120/770 reads (16%) | called by muse, varscan2
- E2F3 | c.963T>A p.P321= | Silent (SNP) | VAF 164/890 reads (18%) | called by muse, varscan2
- FAM221B | c.303G>T p.V101= | Silent (SNP) | VAF 92/455 reads (20%) | called by muse, varscan2
- HAPLN1 | c.120A>G p.L40= | Silent (SNP) | VAF 70/587 reads (12%) | called by muse, varscan2
- PRICKLE2 | c.1005T>C p.T335= (on ENST00000295902; = p.T279= on NM_198859.4) | Silent (SNP) | VAF 160/776 reads (21%) | catalogued as rs1226884715; ClinVar: likely benign; called by muse, varscan2
- DENND2C | c.2755+31T>G | Intron (SNP) | VAF 80/438 reads (18%) | called by muse, varscan2
- FCGR2A | c.107-21C>T | Intron (SNP) | VAF 164/448 reads (37%) | catalogued as rs1465835547; called by muse, varscan2
